Somatic mutation profile of tumor specimen TARGET-10-PARUYU-09A (aliquot TARGET-10-PARUYU-09A-01D) from TARGET case TARGET-10-PARUYU, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.0 years (4,024 days).
Specimen TARGET-10-PARUYU-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d3924a78-4d83-4429-a59c-ee62d24c09ae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARUYU-10A (Blood Derived Normal), aliquot TARGET-10-PARUYU-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/58dfbb64-41aa-4f19-96e7-298122a76627

The open-access MAF lists 16 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, RNA 3, Silent 2, Frame Shift Ins 1, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 6/46 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by mutect2, varscan2
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 14/61 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- NGFR | c.962C>T p.T321M | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as rs762741911, COSV50801821; called by muse, mutect2, varscan2
- PDZK1IP1 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs746288679; called by muse, mutect2, varscan2
- SF3B1 | c.2584G>A p.E862K | Missense Mutation (SNP) | VAF 33/190 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59209855; called by muse, mutect2, varscan2
- XDH | c.2687G>A p.R896Q | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.901); catalogued as rs780573430; called by muse, mutect2, varscan2
- CCR1 | c.989dup p.L331Pfs*20 | Frame Shift Ins (INS) | VAF 47/134 reads (35%) | called by mutect2, pindel, varscan2
- PAQR8 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT tolerated (0.64); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZBTB37 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CFAP206 | c.796C>T p.L266= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV99739705; called by muse, mutect2, varscan2
- DNAJC5 | c.21C>T p.R7= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs1227078334; called by muse, mutect2, varscan2
- AC093536.1 | n.446T>C | RNA (SNP) | VAF 29/103 reads (28%) | called by muse, mutect2, varscan2
- EVPLL | c.-6T>C | 5'UTR (SNP) | VAF 32/64 reads (50%) | called by muse, mutect2, varscan2
- FAM183BP | n.1245C>T | RNA (SNP) | VAF 14/133 reads (11%) | catalogued as rs373142679; called by muse, mutect2, varscan2
- OR4H12P | n.877C>A | RNA (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- PISD | c.322-3861C>T | Intron (SNP) | VAF 12/18 reads (67%) | catalogued as rs367554468; called by muse, varscan2
